Somatic mutation profile of tumor specimen TCGA-EL-A4K4-01A (aliquot TCGA-EL-A4K4-01A-11D-A257-08) from TCGA case TCGA-EL-A4K4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.9 years (12,368 days).
Specimen TCGA-EL-A4K4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 853c7372-5b8c-41a2-977f-8fac8ca391f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4K4-11A (Solid Tissue Normal), aliquot TCGA-EL-A4K4-11A-21D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ea75bd3-e167-4dc5-9d6e-7b8efd832ebc

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BSN | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56517858; called by muse, mutect2, varscan2
- COL6A6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs758753825, COSV62025251; called by muse, mutect2, varscan2
- HSPD1 | c.1703T>C p.M568T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.599); catalogued as rs751438836, COSV100798183; called by mutect2, varscan2
- ITCH | c.1571A>G p.Y524C (on ENST00000262650 / NM_001257137.3; = p.Y483C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV52931943; called by muse, mutect2, varscan2
- NCOR2 | c.4928T>A p.L1643Q | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62298055; called by muse, mutect2
- OR10H2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs549916970, COSV59946004; called by muse, mutect2, varscan2
- EMILIN3 | c.1122G>A p.Q374= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs889927673, COSV60036200; called by muse, mutect2
